Somatic mutation profile of tumor specimen 0E0UHU from CCDI case PBCVJJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0UHU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5123e962-315a-42c4-b4e5-853fdeb3468d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0UI2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4099da47-9bb2-422a-9555-987bedb460f8

The open-access MAF lists 122 somatic variants for this specimen: 82 protein-altering or splice-affecting, 21 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 21, Intron 12, 3'UTR 4, Splice Region 3, 5'UTR 2, Nonsense Mutation 2, Splice Site 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP15 | c.704-6C>A | Splice Region (SNP) | VAF 252/640 reads (39%) | catalogued as rs1026995606; called by muse, mutect2, varscan2
- ATP8B1 | c.2210-1G>C p.X737_splice | Splice Site (SNP) | VAF 92/1018 reads (9%) | catalogued as COSV52180260; called by muse, mutect2
- CDK18 | c.678C>A p.N226K (on ENST00000506784 / NM_212503.3; = p.N196K on NM_002596.4) | Missense Mutation (SNP) | VAF 153/1646 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV63726727, COSV63727625; called by muse, mutect2
- COL24A1 | c.3014G>T p.G1005V | Missense Mutation (SNP) | VAF 132/1322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65316384; called by muse, mutect2, varscan2
- FCAR | c.54G>T p.R18S | Missense Mutation (SNP) | VAF 60/727 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62030137; called by muse, mutect2
- FUT5 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 127/1009 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748322600; called by muse, mutect2, varscan2
- GRM7 | c.1865G>C p.R622P | Missense Mutation (SNP) | VAF 62/1245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM124540, COSV100736180; called by muse, mutect2
- KCNJ16 | c.212G>C p.R71P | Missense Mutation (SNP) | VAF 160/1628 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52252627; called by muse, mutect2, varscan2
- MYH7B | c.3650C>T p.A1217V | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1569059701; called by muse, mutect2
- MYH8 | c.4819G>C p.E1607Q | Missense Mutation (SNP) | VAF 82/1940 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV67968928; called by muse, mutect2
- NTF3 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 88/808 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV58418001; called by muse, mutect2, varscan2
- OPLAH | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 184/1860 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV70679256; called by muse, mutect2
- OSR2 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 118/669 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52558189; called by muse, mutect2, varscan2
- POLK | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 124/1216 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99606454; called by muse, mutect2, varscan2
- SLC2A4RG | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 44/717 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99828596; called by muse, mutect2
- SMPDL3A | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 90/1245 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs199548891, COSV63755449; called by muse, mutect2
- SYNE2 | c.6899G>A p.S2300N | Missense Mutation (SNP) | VAF 114/908 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1291076846; called by muse, mutect2, varscan2
- SYTL2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 30/1000 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60361841; called by muse, mutect2
- TBX15 | c.1615C>A p.Q539K (on ENST00000369429 / NM_001330677.2; = p.Q433K on NM_152380.3) | Missense Mutation (SNP) | VAF 176/1820 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs751471721; called by muse, mutect2
- TTN | c.24328A>G p.I8110V (on ENST00000591111; = p.I7183V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/984 reads (7%) | PolyPhen benign (0); catalogued as rs748483075; called by muse, mutect2
- USP26 | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 167/607 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as COSV63708104, COSV63709150; called by muse, mutect2, varscan2
- ZNF114 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 112/1118 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV100252055; called by muse, mutect2
- ZSCAN25 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 93/1161 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs765707872; called by muse, mutect2
- ABI3BP | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 89/2050 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ALX1 | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 78/1593 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AMD1 | c.960T>G p.F320L | Missense Mutation (SNP) | VAF 78/1418 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- AMIGO2 | c.1469C>A p.A490E | Missense Mutation (SNP) | VAF 182/995 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AP000311.1 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 103/909 reads (11%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- AR | c.2628G>T p.Q876H | Missense Mutation (SNP) | VAF 64/438 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BMP15 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 125/467 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 50/1774 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- C1orf94 | c.1208A>G p.K403R (on ENST00000488417 / NM_001134734.2; = p.K213R on NM_032884.5) | Missense Mutation (SNP) | VAF 127/1459 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- C2orf42 | c.409A>C p.K137Q | Missense Mutation (SNP) | VAF 137/1229 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CAP2 | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 95/1113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- CD163 | c.1422C>G p.A474= | Splice Region (SNP) | VAF 144/1093 reads (13%) | called by muse, mutect2, varscan2
- CDK14 | c.1312G>T p.V438F (on ENST00000380050 / NM_001287135.2; = p.V420F on NM_012395.3) | Missense Mutation (SNP) | VAF 57/1547 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2
- CDKN2AIP | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 77/1490 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2
- CELA3B | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 88/1096 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.121); called by muse, mutect2
- CHRNB3 | c.704T>C p.F235S | Missense Mutation (SNP) | VAF 181/700 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLMN | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 44/749 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- DOCK3 | c.1761C>G p.S587R | Missense Mutation (SNP) | VAF 146/1871 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- GMIP | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 24/630 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- ITGAM | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 58/760 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ITSN1 | c.1554G>T p.E518D | Missense Mutation (SNP) | VAF 83/1239 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.764); called by muse, mutect2
- KCNC3 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 65/538 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KEL | c.282C>G p.N94K | Missense Mutation (SNP) | VAF 173/2068 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- KLHL22 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 120/1623 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2
- LAMB2 | c.2618G>A p.S873N | Missense Mutation (SNP) | VAF 61/566 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGR5 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 131/969 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LIMS2 | c.828G>T p.W276C (on ENST00000355119 / NM_001161403.3; = p.W300C on NM_017980.4) | Missense Mutation (SNP) | VAF 104/872 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LMX1B | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 63/1093 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- LOXHD1 | c.3644A>T p.K1215M | Missense Mutation (SNP) | VAF 200/2926 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- MAGEL2 | c.1378C>A p.Q460K | Missense Mutation (SNP) | VAF 287/1311 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MTBP | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 91/904 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MX2 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 29/624 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NOTCH4 | c.2842C>A p.Q948K | Missense Mutation (SNP) | VAF 101/994 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NT5DC4 | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 92/799 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- OR52E6 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 95/643 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2
- PPP1CB | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 83/805 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- RAD51AP2 | c.169T>G p.L57V | Missense Mutation (SNP) | VAF 103/1600 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RPTOR | c.3130del p.D1044Tfs*33 | Frame Shift Del (DEL) | VAF 74/665 reads (11%) | called by mutect2, varscan2
- SCNN1A | c.1245G>T p.V415= | Splice Region (SNP) | VAF 70/1382 reads (5%) | called by muse, mutect2
- SERPINA12 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 85/768 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SHFL | c.416A>T p.Y139F | Missense Mutation (SNP) | VAF 177/1852 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- SNAI3 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 20/557 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOHLH2 | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 70/826 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- SOWAHA | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- SPINT1 | c.1568A>G p.N523S (on ENST00000344051 / NM_181642.3; = p.N507S on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/578 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- STAB1 | c.2284T>C p.Y762H | Missense Mutation (SNP) | VAF 64/1468 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2
- SUDS3 | c.213-1G>T p.X71_splice | Splice Site (SNP) | VAF 36/810 reads (4%) | called by muse, mutect2
- SYCP3 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 135/1238 reads (11%) | called by muse, mutect2, varscan2
- TAF1L | c.2280G>T p.Q760H | Missense Mutation (SNP) | VAF 168/1294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TANC2 | c.10A>C p.N4H | Missense Mutation (SNP) | VAF 96/1090 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- UBQLN1 | c.11G>C p.S4T | Missense Mutation (SNP) | VAF 68/1098 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2
- UGT2A2 | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 42/758 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDFY4 | c.491C>A p.P164Q | Missense Mutation (SNP) | VAF 82/1131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNK1 | c.1502A>T p.K501I | Missense Mutation (SNP) | VAF 44/1474 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- WT1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZC3H4 | c.1728C>A p.Y576* | Nonsense Mutation (SNP) | VAF 26/754 reads (3%) | called by muse, mutect2
- ZNF10 | c.1305T>G p.C435W | Missense Mutation (SNP) | VAF 67/1572 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF578 | c.809A>G p.E270G | Missense Mutation (SNP) | VAF 29/763 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- ZNF594 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 186/723 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by mutect2, varscan2
- AP002512.3 | c.45A>T p.L15= | Silent (SNP) | VAF 296/1081 reads (27%) | called by muse, mutect2, varscan2
- CMYA5 | c.3075A>G p.S1025= | Silent (SNP) | VAF 143/1247 reads (11%) | called by muse, mutect2, varscan2
- CPQ | c.828T>C p.T276= | Silent (SNP) | VAF 40/714 reads (6%) | called by muse, mutect2
- DENND4B | c.837C>T p.Y279= | Silent (SNP) | VAF 72/1552 reads (5%) | catalogued as rs370814413; called by muse, mutect2
- DLC1 | c.972C>A p.T324= | Silent (SNP) | VAF 43/300 reads (14%) | called by muse, mutect2, varscan2
- DNAH17 | c.7797C>A p.A2599= | Silent (SNP) | VAF 187/1055 reads (18%) | called by muse, mutect2, varscan2
- DNAH3 | c.7608C>A p.T2536= | Silent (SNP) | VAF 45/866 reads (5%) | catalogued as COSV54531348, COSV99770748; called by muse, mutect2
- H1-7 | c.138C>T p.V46= | Silent (SNP) | VAF 60/798 reads (8%) | catalogued as COSV100622241; called by muse, mutect2
- HAS1 | c.477G>T p.T159= | Silent (SNP) | VAF 97/978 reads (10%) | called by muse, mutect2, varscan2
- HERC1 | c.10824G>T p.L3608= | Silent (SNP) | VAF 74/1124 reads (7%) | called by muse, mutect2
- HMCN2 | c.9381C>T p.T3127= | Silent (SNP) | VAF 75/685 reads (11%) | catalogued as rs750480362; called by muse, mutect2, varscan2
- ITLN1 | c.291C>T p.G97= | Silent (SNP) | VAF 160/1630 reads (10%) | catalogued as rs765936465; called by muse, mutect2
- KCNJ5 | c.795C>T p.D265= | Silent (SNP) | VAF 118/321 reads (37%) | catalogued as rs757895735, COSV57971194; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLK12 | c.141C>T p.C47= | Silent (SNP) | VAF 76/1376 reads (6%) | catalogued as rs375828206; called by muse, mutect2
- MEGF10 | c.2019T>C p.C673= | Silent (SNP) | VAF 88/1788 reads (5%) | called by muse, mutect2
- POM121L2 | c.2520C>A p.T840= | Silent (SNP) | VAF 142/1490 reads (10%) | called by muse, mutect2
- REXO1 | c.3438C>T p.S1146= | Silent (SNP) | VAF 65/1511 reads (4%) | catalogued as rs912463133, COSV50075148; called by muse, mutect2
- SSH1 | c.567C>T p.C189= | Silent (SNP) | VAF 210/1248 reads (17%) | catalogued as rs1251217882, COSV58456092; called by muse, mutect2, varscan2
- TBXAS1 | c.1077C>A p.T359= | Silent (SNP) | VAF 116/2968 reads (4%) | called by muse, mutect2
- UTY | c.2211C>T p.G737= | Silent (SNP) | VAF 196/221 reads (89%) | called by muse, mutect2, varscan2
- ZNF777 | c.1053T>G p.S351= | Silent (SNP) | VAF 344/1187 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1701+72T>G | Intron (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 46/1450 reads (3%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- CRLS1 | c.306+781A>T | Intron (SNP) | VAF 70/377 reads (19%) | called by muse, mutect2, varscan2
- DAZAP2 | chr12:51246082 G>A | 3'Flank (SNP) | VAF 267/1651 reads (16%) | catalogued as rs200619808; called by muse, mutect2, varscan2
- FAM171B | c.*82A>T | 3'UTR (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 9/98 reads (9%) | called by muse, varscan2
- GLT6D1 | c.-2G>A | 5'UTR (SNP) | VAF 105/728 reads (14%) | catalogued as COSV100874514; called by muse, mutect2, varscan2
- HDLBP | c.1080+35G>C | Intron (SNP) | VAF 27/287 reads (9%) | catalogued as rs1330776382; called by muse, mutect2, varscan2
- KHSRP | c.1888+25dup | Intron (INS) | VAF 50/412 reads (12%) | catalogued as rs760905596; called by mutect2, varscan2
- LILRB5 | c.1255+58del | Intron (DEL) | VAF 14/112 reads (13%) | catalogued as COSV60260791; called by mutect2, varscan2
- MKS1 | c.*1C>A | 3'UTR (SNP) | VAF 84/1234 reads (7%) | called by muse, mutect2
- PSD4 | c.2457+13C>A | Intron (SNP) | VAF 34/796 reads (4%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 30/254 reads (12%) | called by muse, varscan2
- STK40 | c.1089+52C>T | Intron (SNP) | VAF 40/438 reads (9%) | called by muse, mutect2
- THBS1 | c.1646-73T>A | Intron (SNP) | VAF 19/241 reads (8%) | called by muse, mutect2
- THSD4 | c.-80+14107T>C | Intron (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- ZC3H12A | c.444-53G>T | Intron (SNP) | VAF 56/474 reads (12%) | called by muse, varscan2
- ZNF320 | c.*90G>T | 3'UTR (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2
